Gene-level copy-number profile of tumor specimen C3N-02259-01 from CPTAC case C3N-02259, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 84.7 years (30,932 days).
Specimen C3N-02259-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54bd9724-7841-4791-a8d1-08f09e9d7c85.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02259-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/144a14b4-ef19-4551-bcef-5411e30e402f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 2,588; copy number 2: 52,475; copy number 3: 252; copy number 4: 2,914; copy number 37: 2; copy number 38: 17; copy number 39: 21; copy number 40: 18; copy number 41: 10; copy number 99: 16; copy number 102: 1; copy number 146: 2.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–23,438,700, 22 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr10:63,465,229–63,489,638, 2 genes (within-gene range 0–1): JMJD1C-AS1, AC022022.1.
- chr10:64,036,345–64,620,922, 3 genes: AC012558.1, DBF4P1, RPL17P35.
- chr10:65,054,460–65,315,080, 4 genes: NEK4P3, MYL6P3, AL513321.1, AL592466.1.
- chr10:65,912,523–67,918,390, 17 genes: CTNNA3, AC022017.1, AL607023.1, LRRTM3, AL139240.1, RPL7AP51, MIR7151, AKR1B10P1, RPL21P92, DNAJC12, RNU6-1250P, RN7SL394P, DNAJC19P1, AL133551.1, RNU6-523P, RPL12P8, SIRT1.
- chr10:87,396,561–88,606,976, 21 genes: FAM245A, AL355334.1, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ.
- chr10:88,699,683–89,139,458, 18 genes: NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 87 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:201,829,149–202,096,978, 17 genes, copy number 38 (within-gene range 2–38): IPO9, MIR6739, SHISA4, AL513217.1, LMOD1, TIMM17A, SNORA70H, RPL10P4, RNPEP, ELF3-AS1, MIR6740, ELF3, AL691482.3, AL691482.1, AL691482.2, Y_RNA, CRIP1P3.
- chr1:202,861,754–203,024,848, 10 genes, copy number 39: ACTG1P25, RABIF, KLHL12, HNRNPA1P59, Y_RNA, ADIPOR1, CYB5R1, MGAT4FP, AC096632.1, TMEM183A.
- chr1:203,765,177–204,041,265, 11 genes, copy number 40: LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303.
- chr1:204,218,853–204,562,521, 11 genes, copy number 39: PLEKHA6, AL592114.3, AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74.
- chr1:209,267,798–209,328,535, 2 genes, copy number 41: ATP5MC2P1, LINC01696.
- chr1:211,442,274–211,442,806, 1 gene, copy number 40: ARPC3P2.
- chr1:218,459,265–218,541,899, 2 genes, copy number 37: LINC02869, U3.
- chr1:221,133,865–221,742,089, 6 genes, copy number 40: AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, DUSP10.
- chr1:222,737,207–223,364,178, 8 genes, copy number 41: FAM177B, AL392172.1, DISP1, NDUFB1P2, TLR5, AL359979.2, AL359979.1, SUSD4.
- chr7:54,542,325–55,595,006, 19 genes, copy number 99–146: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2.

Autosomal genes at a single copy (total copy number 1): 2,587. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
